Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A855, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A855-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD 8-3
Carcinoma, papillary renal
cell 826013
Site: R Kidney ABS C64.9
JUN 11/29/13

ADDENDUM

Addendum Comment

A TTF-1 immunohistochemistry stain performed on section #10 of the renal tumor is negative. The control is appropriate. The diagnosis remains unchanged.

This immunohistochemistry test(s) was developed and its performance characteristics determined by the

. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

End of Addendum Report or Additional Results

Staff Pathologist

PATHOLOGIC DIAGNOSIS

KIDNEY, RIGHT, NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA, TYPE 1
- 12.1 CM IN THE LARGEST DIMENSION
- FUHRMAN GRADE 3
- LIMITED TO KIDNEY
- EXTENSIVE NECROSIS
- NO SARCOMATOID TRANSFORMATION
- NO LYMPHOVASCULAR OR LYMPHATIC INVASION
- MARGINS FREE

Tumor Staging (Pathology)

Anatomic site of cancer: Right kidney

Histologic type: Papillary renal cell carcinoma

Fuhrman grade: 3 Tumor size (cm): 12.1 cm in the largest dimension

Primary tumor (T): T2b

Lymph node (N): NX

Distant metastasis (M): MX

Stage grouping: Stage II

Site of distant metastasis: Not known

[page 2 of 3]
Surgical margins: Free

Comment: The finding was communicated via secure email with

Staff Pathologist

Intraoperative Consultation

Kidney, right, nephrectomy:

- Tumor identified (gross only)

- Verbally reported to at

Staff Pathologist

Pathology Resident

Pertinent Clinical Information

History of right renal mass

Gross Description

Specimen Material: Right kidney

Received fresh for intraoperative consultation, labeled "RIGHT KIDNEY" is a 621 gm, 14.5 x 12.2 x 7.5 cm right nephrectomy specimen containing a 13.7 x 11.2 x 7.3 kidney with a 1.3 cm in length x 0.3 cm in diameter ureter, a 0.8 cm in length x 0.3 cm in diameter artery with a 0.4 cm in length x 0.5 cm in diameter vein.

There is abundant attached adipose tissue. No adrenal gland is identified. The Gerota's fascia margin is inked black. The cut surface shows a 12.1 x 9.4 x 4.6 cm yellow to black and hemorrhagic mass involving 85% of the kidney which is located 0.3 cm from the inked margin and does not appear to be involving the attached fat, is 4.5 cm from the artery, vein, ureter, and is 2.6 cm from the renal pelvis. The mass is 95% solid and 5% cystic.

The urothelium is gray-white and smooth. The remaining kidney parenchyma is beefy red and gray-brown and the corticomedullary junction is well-defined.

The cortex measures 1.4 cm thick. No lymph node is identified.

Representative sections are submitted as follows:

1 vascular and ureteral margins

2-4 mass to inked margin

5-18 mass-1 block per cm to landmark-pelvis, fat, normal parenchyma

19 cortex and medulla

[page 3 of 3]
Pathology Assistant

Pathology Resident

Microscopic Description

This is a papillary renal cell carcinoma with extensive tumor necrosis. No sarcomatoid transformation, perineural or lymphovascular invasion is seen. Tumor is confined to the kidney. Vascular and uretral margins are negative.

The staff pathologist listed below has reviewed this case.

****Electronically Signed Out****

Staff Pathologist

Source: NCI Genomic Data Commons file 80e43c5e-8e0f-4c3a-a4a3-0b74982bfa80 (TCGA-MH-A855.C21AC32C-3D4D-4942-AFDB-5F237985D552.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).